Gene-level copy-number profile of tumor specimen TCGA-NC-A5HQ-01A from TCGA case TCGA-NC-A5HQ, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.6 years (25,781 days).
Specimen TCGA-NC-A5HQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.4431b34d-2124-4f74-a453-6d12e4e76c30.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4d8b6e8f-ca31-4e33-b9cf-717793ed5d83

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 865; copy number 2: 28,007; copy number 3: 18,862; copy number 4: 8,617; copy number 5: 2,350; copy number 6: 111; copy number 7: 191; copy number 8: 793; copy number 11: 15; copy number 14: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HQ-01A-11D-A26L-01): tumor purity 0.5, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,461 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:51,925,692–55,419,895, 51 genes, copy number 5 (within-gene range 4–5): AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3, AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A.
- chr2:57,907,629–72,826,041, 283 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:78,597,911–83,657,842, 45 genes, copy number 5: AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 5–14 (broad region; genes not listed).
- chr8:111,621,458–131,432,869, 237 genes, copy number 5–6 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 5 (broad region; genes not listed).
- chr14:21,841,240–22,509,406, 89 genes, copy number 5 (broad region; genes not listed).
- chr18:11,326,270–12,929,643, 64 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr19:53,722,166–54,012,669, 42 genes, copy number 6–11: MIR520G, MIR516B2, MIR526A2, MIR518E, MIR518A1, RNU6-980P, MIR518D, MIR516B1, MIR518A2, MIR517C, MIR520H, RNU6-982P, MIR521-1, RNU6-751P, MIR522, MIR519A1, MIR527, MIR516A1, MIR1283-2, RNU6-1041P, MIR516A2, AC011453.1, MIR519A2, RNU6-165P, HMGN1P32, SEPTIN7P8, AC008753.1, AC008753.3, MIR371A, MIR371B, MIR372, MIR373, AC008753.2, NLRP12, MYADM-AS1, MYADM, AC008440.1, PRKCG, CACNG7, CACNG8, MIR935, CACNG6.

Autosomal genes at a single copy (total copy number 1): 864. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
